Gene-level copy-number profile of tumor specimen ALCH-B6DF-TTP1-A from ALCHEMIST case ALCH-B6DF, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 35.4 years (12,912 days).
Specimen ALCH-B6DF-TTP1-A: Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file dd59a754-c30a-43e6-b2fb-2a39d98e2485.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-B6DF-NB1-A; Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,226 have no estimate.
https://portal.gdc.cancer.gov/files/312a4694-16c5-408f-975b-ff847f102bd6

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 36; copy number 1: 11,809; copy number 2: 42,247; copy number 3: 4,286; copy number 4: 3; copy number 5: 5; copy number 6: 9; copy number 8: 2.

Homozygous deletions (total copy number 0; autosomes only): 36 genes in 6 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:257,864–522,928, 10 genes (within-gene range 0–1): AP006222.1, AP006222.2, RPL23AP24, AL732372.1, AL732372.2, WBP1LP7, OR4F29, CICP7, AL732372.3, U6.
- chr1:50,398,825–50,423,443, 3 genes: HMGB1P45, FCF1P6, DMRTA2.
- chr15:25,232,387–25,250,940, 11 genes (within-gene range 0–1): SNORD115-34, SNORD115-35, SNORD115-36, SNORD115-37, SNORD115-38, SNORD115-39, SNORD115-40, SNORD115-41, SNORD115-42, SNORD115-43, SNORD115-44.
- chr16:70,661,204–70,801,160, 9 genes (within-gene range 0–1): MTSS2, AC020763.4, VAC14, AC020763.3, AC020763.1, VAC14-AS1, AC020763.5, AC020763.2, AC027281.1.
- chr17:32,280,387–32,280,953, 1 gene (within-gene range 0–1): AC026620.1.
- chr22:30,902,219–30,932,449, 2 genes (within-gene range 0–1): EIF4HP2, MORC2-AS1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 16 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr5:135,742,462–135,746,356, 1 gene, copy number 5: AC011431.1.
- chr8:58,552,924–58,582,859, 1 gene, copy number 5: SDCBP.
- chr9:40,130,921–40,153,147, 2 genes, copy number 8: AL773545.1, AL773545.2.
- chr14:34,541,044–34,546,877, 3 genes, copy number 5: AL445363.3, AL445363.1, RNU1-27P.
- chr22:18,533,646–18,719,341, 9 genes, copy number 6: PI4KAP1, AC023490.1, RN7SKP131, RIMBP3, Metazoa_SRP, SUSD2P2, CA15P2, PPP1R26P2, PPP1R26P4.

Autosomal genes at a single copy (total copy number 1): 11,809. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
